Gene-level copy-number profile of tumor specimen TCGA-DX-A23Z-01A from TCGA case TCGA-DX-A23Z, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 74.9 years (27,357 days).
Specimen TCGA-DX-A23Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.2931d244-8f70-4768-9820-9f8667bd6571.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A23Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/540cde18-ce47-4a98-97ac-2e1cced51506

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,409; copy number 2: 55,577; copy number 3: 55; copy number 4: 182; copy number 5: 664; copy number 6: 389; copy number 7: 48; copy number 8: 213; copy number 9: 34; copy number 10: 59; copy number 11: 43; copy number 12: 26; copy number 13: 5; copy number 14: 38; copy number 15: 4; copy number 16: 13; copy number 17: 24; copy number 18: 31; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,592 genes in 92 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,189,735–191,425,389, 24 genes, copy number 6: HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr2:199,867,396–205,620,162, 144 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:217,693,895–222,298,998, 128 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr2:224,470,150–228,379,773, 48 genes, copy number 5 (within-gene range 2–5): CUL3, ANKRD49P1, CCDC195, DOCK10, MIR4439, NYAP2, AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4, COL4A3, MFF-DT, MFF, TM4SF20, SCYGR1, MIR5703, AGFG1, SCYGR9, SCYGR2, SCYGR10, C2orf83, SCYGR3, AC064853.1, SCYGR4, SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1.
- chr4:336,258–1,982,207, 61 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:56,099,680–56,382,075, 10 genes, copy number 6: ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17.
- chr6:28,378,955–28,534,955, 9 genes, copy number 8: ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, Z98745.2, Z98745.1, GPX6, GPX5.
- chr6:30,908,207–31,225,058, 26 genes, copy number 6 (within-gene range 2–6): GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3, AL662844.4, HCG27, AL662844.3, AL662844.1, AL662844.2.
- chr6:31,394,289–32,195,523, 110 genes, copy number 6 (broad region; genes not listed).
- chr6:32,628,179–33,200,665, 35 genes, copy number 6: HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1, MTCO3P1, AL662789.1, HLA-DQB3, HLA-DQA2, MIR3135B, HLA-DQB2, HLA-DOB, AL669918.1, TAP2, PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2, HLA-DMA, BRD2, AL645941.1, AL645941.3, HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB.
- chr6:33,721,662–33,927,631, 8 genes, copy number 5: IP6K3, LEMD2, MLN, AL138889.3, LINC01016, AL138889.2, AL138889.1, MIR7159.
- chr6:34,792,015–36,144,524, 41 genes, copy number 6 (within-gene range 2–6): UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11, SCUBE3, Z97832.2, ZNF76, Z97832.1, DEF6, PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13.
- chr6:36,697,826–37,699,306, 29 genes, copy number 5 (within-gene range 2–5): RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1.
- chr6:143,807,092–144,064,599, 8 genes, copy number 8 (within-gene range 2–8): AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2.
- chr6:148,237,585–149,411,613, 16 genes, copy number 9–11 (within-gene range 1–11): AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1.
- chr6:153,231,320–153,938,992, 13 genes, copy number 9: AL590867.1, AL590867.2, AL358134.1, RNA5SP225, MTCO2P31, AL603908.1, MTATP6P31, MTCO3P31, MTND3P20, MTND4LP20, MTND4P13, RNU6-896P, HMGB3P19.
- chr7:114,560,961–115,791,049, 13 genes, copy number 8: AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2.
- chr9:128,160,265–128,393,510, 16 genes, copy number 17: C9orf16, CIZ1, DNM1, MIR199B, MIR3154, GOLGA2, SWI5, TRUB2, AL359091.3, COQ4, SLC27A4, TMSB4XP4, URM1, AL359091.1, MIR219A2, MIR219B.
- chr10:43,385,617–43,981,102, 26 genes, copy number 5 (within-gene range 2–5): HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2, ZNF239, AL450326.3, CAP1P2, ZNF485, ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1, SPRING1P1, UQCRHP3, ELOCP30, LINC02658, LINC00840, HNRNPA3P1, LINC02659, LINC00841, AL139237.1.
- chr10:44,937,508–45,147,221, 10 genes, copy number 5 (within-gene range 2–5): AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1, AL358394.3, DUXAP4, RPS19P7.
- chr10:46,337,224–50,965,220, 120 genes, copy number 5 (broad region; genes not listed).
- chr10:71,964,395–79,067,895, 169 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr11:73,646,178–74,311,640, 24 genes, copy number 5 (within-gene range 2–5): PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1.
- chr11:74,397,549–74,685,505, 12 genes, copy number 6: AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297.
- chr11:74,807,739–77,474,635, 79 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:77,878,720–79,441,030, 27 genes, copy number 5 (within-gene range 2–5): INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1.
- chr11:81,821,272–82,817,741, 9 genes, copy number 6: MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3.
- chr11:101,890,674–104,252,651, 54 genes, copy number 6–12: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1.
- chr11:108,308,519–109,120,986, 11 genes, copy number 5–10: C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349.
- chr11:111,726,908–112,022,653, 16 genes, copy number 10 (within-gene range 2–10): PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8, CRYAB, HSPB2, HSPB2-C11orf52, C11orf52, DIXDC1, RNA5SP351, AP000907.1.
- chr11:124,009,655–124,274,581, 18 genes, copy number 7–13: OR10G5P, OR10G4, OR10G9, OR10G8, OR10G7, OR10D5P, OR10D4P, OR10N1P, VWA5A, OR10D1P, OR10D3, OR8F1P, OR8G3P, OR8G2P, OR8G7P, OR8G1, OR8G5, SLC5A4P1.
- chr11:124,566,660–124,834,487, 17 genes, copy number 11: OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, NRGN, AP000866.5, VSIG2, ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4.
- chr12:40,393,395–41,072,415, 6 genes, copy number 10 (within-gene range 2–10): MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.
- chr12:57,619,527–58,395,138, 35 genes, copy number 14–18: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:63,760,358–64,162,217, 13 genes, copy number 16 (within-gene range 2–16): AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr12:65,824,460–66,254,622, 14 genes, copy number 11 (within-gene range 2–11): HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1.
- chr12:67,424,272–67,753,817, 8 genes, copy number 17: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:68,805,011–68,971,570, 9 genes, copy number 18: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,359,710–70,920,738, 29 genes, copy number 7–22 (within-gene range 2–22): YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:71,439,798–71,835,396, 13 genes, copy number 10: LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
